Surgical pathology report (de-identified scan), TCGA case TCGA-29-1696, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-1696-01A (Primary Tumor).

[page 1 of 3]
Surg Path

CLINICAL HISTORY:

Pelvic mass-abdominal/pelvic mass (CA125= 1487 per

TCGA-29-1696

GROSS EXAMINATION:

- A. "Right ovary and tube (AF1)". Received fresh is a 31.6 gram 4.2 x 3.2 x 1.8 cm ovary and unremarkable 6.3 cm long fimbriated fallopian tube (average diameter of 0.5 cm) (A2). Extensive tan, friable, papillary excrescences project 2.5 cm off the ovarian serosa (Frozen AF1, remnant A1). Cut section discloses a firm, yellow poorly defined central 0.7 cm nodule (A3-4).
- B. "Right inguinal mass", received fresh and placed in formalin. A 2.1 x 1.1 x 0.5 cm specimen of light tan fibromembranous tissue which is bisected and submitted in toto in B1.
- C. "Left gutter tumor". Received fresh is a 3.9 x 2.2 x 1.5 cm specimen of tan fibromembranous and yellow fibroadipose tissue. It contains two 1.5 cm cysts with diameters of 1.5 cm each consisting of thin smooth walls and each contains yellowish mucoid material. One has a 0.4 cm yellow papillary excrescence projecting into the cyst lumen (C1).
- D. "Cul-de-sac nodule", received fresh and placed in formalin. A 1.1 x 1 x 0.6 cm aggregate of tan fibromembranous tissue submitted in toto in block D1.
- E. "Left pelvic lymph node", received fresh and placed in formalin. A 2 x 1.5 x 0.3 cm aggregate of fibromembranous tan tissue containing lymph node candidates and submitted in toto in block E1.
- F. "Left tube and ovary", received fresh and placed in formalin. A 15.1 gram specimen consisting of a 4.6 cm long fimbriated fallopian tube with a diameter of 0.5 cm, a 2.6 x 2 x 1 cm ovary and attached soft tissue. The ovary surface is smooth, tan, glistening except for a dark tan, friable, papillary serous excrescence projecting focally from the ovary surface and measuring approximately 1 x 1 x 1 cm. The parenchyma is grossly unremarkable. Section of ovary with adjacent excrescence and fallopian tube submitted in block F1 and other ovary sections in blocks F2-3.
- G. "Omentum", received fresh and placed in formalin a 15 x 10 x 5.5 cm aggregate of yellow fibroadipose tissue containing multiple firm tan nodules with a maximum diameter of 2 cm whose cut surfaces are solid white and grossly metastases (G1).
- H. "Bladder sac, peritoneum", received fresh and placed in formalin. A 3.5 x 2.5 x 1 cm aggregate of tan fibromembranous tissue which contains a 0.7 cm diameter cyst filled with clear serous fluid and is thin walled and translucent except for at the base which is solid, light tan, papillary in appearance and section submitted in block H1.
- I. "Uterus and cervix", received fresh and placed in formalin. A 115.3 gram, 10.5 x 5.5 x 4.1 cm uterus is received. The serosal surface is tan and has a granular consistency. The cervix is white, smooth and glistening with a diameter of 2.8 cm. The external os diameter is 0.3 cm and the endometrial canal has a tan herringbone mucosa containing a large amount of mucin. The endometrial cavity measures 3 cm from cornu to cornu and 4.8 cm long. The endometrium and myometrium are grossly unremarkable with average measurements of 0.2 and 2.5 cm respectively.

BLOCK SUMMARY:

I1- anterior cervix

[page 2 of 3]
- I2- posterior cervix
- I3- anterior endomyometrium
- I4- posterior endomyometrium

J. "Right pelvic lymph nodes", received fresh and placed in formalin. A 6.5 x 5 x 3 cm aggregate of yellow fibroadipose tissue containing lymph node candidates is received. Lymph node candidates submitted in blocks J1-2.

K. "Nodule from sigmoid mesentery", received fresh and placed in formalin. Multiple fragments of fibromembranous and yellow fibroadipose tissue with an aggregate 5.3 x 2.5 x 1 cm is received. Representative in block K1.

L. "Right inguinal hernia sac", received fresh and placed in formalin. A 3 x 1.5 x 1 cm dark tan fibromembranous tissue with a smooth glistening serosal surface is received. Representative in L1.

INTRA OPERATIVE CONSULTATION:

A. "Right ovary and tube": AFl-serous adenocarcinoma

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

DIAGNOSIS:

SPECIMEN TYPE: HYSTERECTOMY, OOPHORECTOMY & LYMPH NODES:

A. "RIGHT OVARY":

TYPE: SEROUS ADENOCARCINOMA
FIGO GRADE: 2
TUMOR SIZE: 4.2 X 3.2 X 1.9 CM.
WEIGHT: 32 GRAMS
SEROSA: TUMOR ON SURFACE
ADDITIONAL FINDINGS: NONE
PATH STAGING: 3C FIGO

TCGA-29-1696

SPECIMENS WITH METASTATIC/IMPLANTED TUMOR:

- C. LEFT GUTTER TUMOR.
- D. CUL DE SAC NODULE.
- F. SEROSA OF LEFT OVARY.
- G. OMENTUM.
- H. BLADDER SAC PERITONEUM.
- J. RIGHT PELVIC LYMPH NODES (FIVE OF TWELVE LYMPH NODES POSITIVE).
- K. NODULE FROM SIGMOID MESENTERY.
- L. RIGHT INGUINAL HERNIA SAC.

THE FOLLOWING CONTAINS PSAMMOMA BODIES, BUT NO TUMOR:

- B. RIGHT INGUINAL MASS.

SPECIMENS FREE OF TUMOR:

- A. RIGHT FALLOPIAN TUBE.
- E. LEFT PELVIC LYMPH NODES NO TUMOR IN 3 LYMPH NODES (0/3).
- F. LEFT FALLOPIAN TUBE.
- I. UTERUS, 115 GRAMS
ENDOMETRIUM: PSEUDODECIDUA
MYOMETRIUM, CERVIX & SEROSA: NO PATHOLOGIC DIAGNOSIS

NOTE: Information on pathology staging and the operative procedure is being transmitted to this Institution's Cancer Registry as required for accreditation purposes by the Commission on Cancer. Pathology staging is based solely upon the current tissue specimen being evaluated, and does not incorporate information on any specimens submitted separately to our Cytology section, past pathology information, imaging studies, or clinical or operative findings. Anatomic pathology staging is only a component to be considered in determining the clinical stage, but should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

[page 3 of 3]
I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]
[REDACTED]

CI ADDENDUM 1:

Please see Image Cytometry Report [REDACTED] for results of supplementary tests.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]

Performed by:

[REDACTED]

[REDACTED]

TCGA-29-1696

[REDACTED]

Source: NCI Genomic Data Commons file baeccfca-fd3e-40b3-b93a-aa3373723ad1 (TCGA-29-1696.5E817943-3108-4838-BF8C-85C4507EB873.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).